Somatic mutation profile of tumor specimen TCGA-DD-AAEK-01A (aliquot TCGA-DD-AAEK-01A-11D-A40R-10) from TCGA case TCGA-DD-AAEK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.4 years (18,757 days).
Specimen TCGA-DD-AAEK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09a7a1c7-162a-4829-b46c-a3d4ad53d903.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEK-10A (Blood Derived Normal), aliquot TCGA-DD-AAEK-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f51a1307-fdb7-4962-bde8-ce41bef0b3bf

The open-access MAF lists 94 somatic variants for this specimen: 74 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Splice Site 8, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 14/112 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIN1 | c.2441C>A p.A814D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1131691870, COSV100160588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs748929112, COSV100206829, COSV60198875; called by muse, mutect2, varscan2
- AKR1B10 | c.947A>T p.Y316F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100610224; called by muse, mutect2, varscan2
- ARID2 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370535448, COSV57605293; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99958999; called by muse, mutect2, varscan2
- C6orf118 | c.761A>C p.Q254P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100024891; called by muse, mutect2, varscan2
- C8orf76 | c.496A>T p.N166Y | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.483); catalogued as COSV99415185; called by muse, mutect2, varscan2
- CASKIN2 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100395554; called by muse, mutect2, varscan2
- CCNL2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101275711; called by muse, mutect2, varscan2
- CD109 | c.1679A>C p.K560T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV99754267; called by muse, mutect2, varscan2
- CD19 | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs774259710, COSV100218228; called by muse, mutect2, varscan2
- CEP126 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | catalogued as rs757264461, COSV54822167; called by muse, mutect2, varscan2
- CLTC | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1408457952, COSV99292717; called by muse, mutect2, varscan2
- CSNK1E | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV63292501; called by muse, mutect2, varscan2
- CTNND2 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.033); catalogued as COSV100479625; called by muse, mutect2, varscan2
- CYSLTR2 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV99935343; called by muse, mutect2, varscan2
- DCLK1 | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99712475; called by muse, mutect2, varscan2
- DOCK1 | c.2381A>C p.K794T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99731713; called by muse, mutect2
- FBN3 | c.1759T>C p.C587R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99561524; called by muse, mutect2, varscan2
- FOXRED1 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99702945; called by muse, mutect2, varscan2
- GRM7 | c.1604C>A p.T535K | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100737776; called by muse, mutect2, varscan2
- HOXB2 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV100344770; called by muse, mutect2, varscan2
- HSP90AA1 | c.224A>T p.E75V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99355453; called by muse, mutect2, varscan2
- KBTBD2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100406562; called by muse, mutect2, varscan2
- KIFC2 | c.681+1G>A p.X227_splice | Splice Site (SNP) | VAF 25/195 reads (13%) | catalogued as COSV100023919; called by muse, mutect2, varscan2
- KNG1 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53977566, COSV99405771; called by muse, mutect2, varscan2
- LBR | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 63/434 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99687602; called by muse, mutect2, varscan2
- LRP1 | c.10106G>T p.C3369F | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99676738; called by muse, mutect2, varscan2
- MAP3K1 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 71/242 reads (29%) | catalogued as COSV68122969; called by muse, mutect2, varscan2
- MAP3K2 | c.1766A>G p.Y589C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370911611; called by muse, mutect2, varscan2
- MINDY3 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99510927; called by muse, mutect2, varscan2
- MS4A4A | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100557892; called by muse, mutect2, varscan2
- MTREX | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 84/528 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1358018399, COSV99287541; called by muse, mutect2, varscan2
- NLGN2 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259553; called by muse, mutect2, varscan2
- NRXN1 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as rs202118977, COSV101276789, COSV101278897; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFM4 | c.1322A>C p.Y441S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99524502; called by muse, mutect2, varscan2
- OVGP1 | c.1828T>G p.L610V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100868246; called by muse, mutect2, varscan2
- PARD3 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100401686; called by muse, mutect2
- PCDH15 | c.3441A>C p.K1147N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); catalogued as COSV100225432; called by muse, mutect2, varscan2
- PLCG2 | c.850T>A p.F284I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100842525; called by muse, mutect2, varscan2
- PLEKHO1 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99215333; called by muse, mutect2, varscan2
- PNMA8A | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV58139218; called by muse, mutect2, varscan2
- PPOX | c.1099-2A>C p.X367_splice | Splice Site (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99237681; called by muse, mutect2, varscan2
- PRXL2A | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100939820; called by muse, mutect2, varscan2
- PSAPL1 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1388702475, COSV100040620; called by muse, mutect2, varscan2
- PSMD4 | c.1052C>G p.A351G | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV100924685; called by muse, mutect2
- R3HCC1L | c.2003+1G>A p.X668_splice (on ENST00000612478 / NM_001256619.2; = p.X654_splice on NM_014472.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV54400336; called by muse, mutect2, varscan2
- RAB6D | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs775458306; called by muse, mutect2, varscan2
- SF3B3 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1334160769, COSV56785225; called by muse, mutect2, varscan2
- SRRM2 | c.3621A>C p.R1207S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100071255; called by muse, mutect2
- STAB1 | c.2883G>T p.L961= | Splice Region (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100402059; called by muse, mutect2
- STRN | c.492-1G>T p.X164_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99815601; called by muse, mutect2, varscan2
- TCP11 | c.311C>A p.P104H (on ENST00000512012; = p.P42H on NM_018679.5) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300260237, COSV99774444; called by muse, mutect2, varscan2
- TET1 | c.4612A>C p.T1538P | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101018677; called by muse, mutect2, varscan2
- TGDS | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99725241; called by muse, mutect2, varscan2
- THBS3 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs761943681, COSV64249907, COSV64250734; called by muse, mutect2, varscan2
- THSD7A | c.2081G>T p.C694F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448833; called by muse, mutect2, varscan2
- THSD7B | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55653508, COSV99756044; called by muse, mutect2, varscan2
- TOX4 | c.1834A>G p.R612G | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99398501; called by muse, mutect2, varscan2
- TRNT1 | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.337); catalogued as COSV99285863; called by muse, mutect2, varscan2
- TRPM8 | c.3231-1G>T p.X1077_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100224398; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1961A>G p.H654R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759923388, COSV99691961; called by muse, mutect2, varscan2
- VARS1 | c.1802A>G p.Y601C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767158154, COSV100791840; called by muse, mutect2, varscan2
- VCL | c.843A>T p.K281N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99281165; called by muse, mutect2, varscan2
- ACOT12 | c.495_496+28del p.X165_splice | Splice Site (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- CCDC17 | c.734_739del p.E245_R247delinsG | In Frame Del (DEL) | VAF 27/136 reads (20%) | called by mutect2, pindel, varscan2
- CHST10 | c.137_138dup p.M47Pfs*5 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- DAXX | c.1252-24_1257del p.X418_splice | Splice Site (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- HACE1 | c.2015-7_2029del p.X672_splice | Splice Site (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- ING5 | c.678del p.K226Nfs*48 | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | called by mutect2, pindel, varscan2
- PTPN9 | c.701_725del p.N234Ifs*13 | Frame Shift Del (DEL) | VAF 18/176 reads (10%) | called by mutect2, pindel
- TAB2 | c.553dup p.I185Nfs*6 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- TUBB1 | c.1348_*3del | Nonstop Mutation (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel
- AC005324.2 | c.768G>A p.E256= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100372020; called by muse, mutect2, varscan2
- ANO2 | c.1329C>T p.F443= (on ENST00000356134 / NM_001278597.3; = p.F447= on NM_001278596.3) | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV59019885, COSV59030174; called by muse, mutect2, varscan2
- FBF1 | c.666A>G p.K222= (on ENST00000586717; = p.K236= on NM_001319193.1) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100045478; called by muse, mutect2, varscan2
- FGF8 | c.531C>T p.P177= (on ENST00000344255 / NM_033164.4; = p.P159= on NM_006119.6) | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100199417; called by muse, mutect2, varscan2
- GRIK1 | c.1215C>A p.G405= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs374777692, COSV100413256; called by muse, mutect2, varscan2
- GTF2IRD2B | c.273C>T p.P91= | Silent (SNP) | VAF 74/1087 reads (7%) | catalogued as rs1269433818; called by muse, mutect2
- HAPLN4 | c.771C>T p.N257= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs745741491, COSV99363963; called by muse, mutect2, varscan2
- NEDD4L | c.1009A>C p.R337= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99896093; called by muse, mutect2, varscan2
- RAPGEF4 | c.1731C>T p.V577= | Silent (SNP) | VAF 59/160 reads (37%) | catalogued as COSV99911289; called by muse, mutect2, varscan2
- SETD2 | c.4065A>G p.K1355= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100339686; called by muse, mutect2, varscan2
- SLC13A1 | c.816C>T p.R272= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99521320; called by muse, mutect2, varscan2
- SLC29A1 | c.789A>G p.K263= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1169695611, COSV100505890; called by muse, mutect2, varscan2
- SORL1 | c.744C>G p.V248= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV99494973; called by muse, mutect2, varscan2
- TMC6 | c.459C>A p.L153= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100130290; called by muse, mutect2
- TMUB1 | c.93G>A p.T31= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as rs1243690279, COSV99879887; called by muse, mutect2, varscan2
- TTYH3 | c.496C>A p.R166= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99350047; called by muse, mutect2, varscan2
- ZHX2 | c.2289G>A p.K763= | Silent (SNP) | VAF 43/195 reads (22%) | catalogued as rs1343824089, COSV100073652; called by muse, mutect2, varscan2
- ZNF439 | c.372T>C p.F124= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as COSV100397533; called by muse, mutect2, varscan2
- ZNF502 | c.1029A>G p.R343= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV56072757, COSV99939812; called by muse, mutect2, varscan2
- ZNF271P | n.1852C>G | RNA (SNP) | VAF 30/148 reads (20%) | called by muse, mutect2, varscan2
